Somatic mutation profile of tumor specimen TCGA-QR-A70J-01A (aliquot TCGA-QR-A70J-01A-11D-A35D-08) from TCGA case TCGA-QR-A70J, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 42.2 years (15,420 days).
Specimen TCGA-QR-A70J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef0d78a0-e40e-410b-8a6c-644d0b90a1b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QR-A70J-10A (Blood Derived Normal), aliquot TCGA-QR-A70J-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3c13556-6721-4e3f-8939-20f17d73a5cb

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 7, Silent 5, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPR137 | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 5/97 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); catalogued as COSV57403886; called by muse, mutect2
- MUC5AC | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 4/39 reads (10%) | SIFT tolerated (1); catalogued as rs1358206863, COSV62253159; called by muse, mutect2
- MYPN | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as rs1301769596, COSV62740920; called by muse, mutect2, varscan2
- ROCK2 | c.3625C>T p.R1209* | Nonsense Mutation (SNP) | VAF 9/86 reads (10%) | catalogued as rs764405852; called by muse, mutect2
- ST6GAL2 | c.230G>A p.R77H | Missense Mutation (SNP) | VAF 15/71 reads (21%) | PolyPhen benign (0); catalogued as rs758806051, COSV64527663; called by muse, mutect2, varscan2
- CLASP2 | c.3103A>C p.N1035H (on ENST00000359576; = p.N1034H on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 24/85 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); called by muse, mutect2, varscan2
- KDM6B | c.4648C>G p.Q1550E | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.21); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- SPINK5 | c.2739G>T p.K913N | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- MMRN1 | c.360C>T p.N120= | Silent (SNP) | VAF 17/89 reads (19%) | catalogued as rs142099842; called by muse, mutect2, varscan2
- PADI3 | c.981C>T p.A327= | Silent (SNP) | VAF 6/47 reads (13%) | called by muse, mutect2, varscan2
- TACC2 | c.6924C>A p.P2308= (on ENST00000334433; = p.P386= on NM_006997.4) | Silent (SNP) | VAF 32/128 reads (25%) | called by muse, mutect2, varscan2
- USP19 | c.2049C>T p.L683= | Silent (SNP) | VAF 43/183 reads (23%) | catalogued as rs1422843026; called by muse, mutect2, varscan2
- WDR62 | c.2424A>T p.P808= | Silent (SNP) | VAF 8/86 reads (9%) | called by muse, mutect2
